CCDI case PBBJIL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c7f7c13f-456e-44e2-86a3-e67c3a2fcc9e

Demographics
Sex at birth: female; Race: white; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Cerebrum; Age at diagnosis: 0.6 years (202 days).

Biospecimens (3 samples)
- Sample 0DA8LA: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DA8MA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DA8MC: Tissue type: Tumor; Specimen type: Solid Tissue.
